CPTAC case C3N-03767 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79ea2d3a-7ab5-4312-a09d-ff7571057e64

Demographics
Sex at birth: female; Race: white; Year of birth: 1951; Vital status: Dead; Days to death: 1,002 days (2.7 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 66.1 years (24,142 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,002 days (2.7 years); Progression or recurrence: yes; Days to last follow up: 897 days (2.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 13 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (4 entries)
- Days to follow up: 491 days (1.3 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 721 days (2.0 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 897 days (2.5 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 897 days (2.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 491 days (1.3 years); Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 62 kg; Height: 158 cm; BMI: 24; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03767-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 204 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03767-21: Section location: Anterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-03767-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03767-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
